Surgical pathology report (de-identified scan), TCGA case TCGA-MB-A5YA, project TCGA-SARC (Sarcoma), tissue source site University of Minnesota, specimen TCGA-MB-A5YA-01A (Primary Tumor).

[page 1 of 3]
TSS ID:

ID:

Date of Sample Procurement:

ICD-0-3
Leiomyosarcoma NOS
path 8890/3
Site: Mesentery C48.1
CGCF Retroperitoneum C48.0
JW 4/29/13

SPECIMEN(S):

Small bowel and sarcoma

FINAL DIAGNOSIS:

Small bowel and sarcoma:

- Leiomyosarcoma, high-grade.
- Surgical margins: All negative.
- Closest, mesenteric margin: 0.5 cm from tumor.
- Small bowel segment with no diagnostic abnormalities.
- Four benign lymph nodes with no evidence of malignancy (0/4 lymph nodes).

COMMENT:

This neoplasm shows high cellularity, prominent atypia, numerous mitoses, necrosis and hemorrhage. The small bowel wall is unaffected; the tumor arose in the mesentery; presumably in mesenteric vessel wall. Previous biopsy of this tumor shows it to be negative for CD117 (Ckit-negative).

CLINICAL HISTORY:

The patient is male with history of sarcoma. Operative

[page 2 of 3]
procedure: Small bowel and sarcoma resection.

GROSS:

One formalin-filled container is received labeled with the patient's Name and medical record number.

The container is additionally labeled "small and sarcoma" and consist of a 71 cm in length by 2.5 cm in diameter segment of small bowel with attached large amount of mesenteric adipose tissue. Both resection margins are previously stapled closed. The serosal surface is red and smooth with no exudate, perforation, or lesions. An 8.5 x 8.4 x 7.3 cm large, round, and solid mass is present within mesenteric adipose tissue. On sectioning, the mass is white, whorled, firm and solid. A 1.8 x 1.5 x 0.7 cm dark red hemorrhagic area is present in the central portion. The mass is 7.5 cm to the bowel, 7.5 and 9.0 cm to bowel resection margins respectively. The mesenteric margin is inked black and the mass is 0.5 cm to the closest margin. Grossly the mass is entirely encapsulated. The bowel is opened to reveal tan and unremarkable mucosa with permanent transverse ridges. A lymph node dissection is performed within mesenteric adipose tissue and lymph nodes ranging from 0.5 to 1.7 cm in greatest dimension are present. Representative tissue was procured for potential future studies.

Summary of Sections:

[page 3 of 3]
A1 - two bowel margins.

A2 - the mass with closest mesenteric margin.

A3-A4 - mass to include hemorrhage.

A5-A11 - mass.

A12-A13 - bowel wall.

A14-A18 - one lymph node in each.

MICROSCOPIC:

Microscopic examination is performed.

Source: NCI Genomic Data Commons file 71446f83-5a3c-40ec-b5d9-584c5830221c (TCGA-MB-A5YA.C25C3402-4C38-4162-ACC2-6FBBC09E94C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).